Somatic mutation profile of tumor specimen TCGA-EB-A41B-01A (aliquot TCGA-EB-A41B-01A-11D-A24R-08) from TCGA case TCGA-EB-A41B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 76.7 years (27,998 days).
Specimen TCGA-EB-A41B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2e41756-22d1-41ae-9474-c0c9289bb504.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A41B-10A (Blood Derived Normal), aliquot TCGA-EB-A41B-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4693c34f-36d3-4bb7-8671-f1f593cc5941

The open-access MAF lists 482 somatic variants for this specimen: 308 protein-altering or splice-affecting, 162 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 278, Silent 162, Nonsense Mutation 21, Intron 6, RNA 4, Splice Site 3, In Frame Del 2, Splice Region 2, Frame Shift Del 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 43/92 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61963254; called by muse, mutect2, varscan2
- ABCB11 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55600021; called by muse, mutect2, varscan2
- ABCB9 | c.1592C>T p.P531L (on ENST00000280560 / NM_019625.4; = p.P488L on NM_019624.3) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs140303524; called by muse, mutect2, varscan2
- AC109583.1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58406517; called by muse, mutect2, varscan2
- ACKR4 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV51442704; called by muse, mutect2, varscan2
- ADAM29 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as rs746704560, COSV63660588, COSV63667714; called by muse, mutect2, varscan2
- ADAM32 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.123); catalogued as COSV65953294; called by muse, mutect2, varscan2
- ADAMTS12 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs1318015724, COSV61256353, COSV61277339; called by muse, mutect2, varscan2
- ADGRG4 | c.6428G>A p.G2143D | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as COSV54965801; called by muse, mutect2, varscan2
- ADGRV1 | c.11732G>A p.G3911E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67980306, COSV67983529; called by muse, mutect2, varscan2
- AGR3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV100124036; called by muse, mutect2, varscan2
- ALG13 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV52643451; called by muse, mutect2, varscan2
- ANK3 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.333); catalogued as rs538354013, COSV55048293; called by muse, mutect2, varscan2
- ANK3 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as COSV55044248; called by muse, mutect2, varscan2
- ANK3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048999; called by muse, mutect2, varscan2
- ANK3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780747, COSV99781189; called by muse, mutect2, varscan2
- ANKRD24 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV53675455; called by muse, mutect2, varscan2
- ANKRD30A | c.2546C>T p.P849L (on ENST00000611781; = p.P793L on NM_052997.2) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64619834; called by muse, mutect2, varscan2
- ANKRD33 | c.611C>T p.P204L (on ENST00000340970 / NM_001304459.2; = p.P329L on NM_182608.4) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56607625, COSV56608291; called by muse, mutect2, varscan2
- ANKRD45 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60960107; called by muse, mutect2, varscan2
- ANO3 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 74/158 reads (47%) | catalogued as rs916142987, COSV56807073; called by muse, mutect2, varscan2
- AP002748.5 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1310835731, COSV59151525; called by muse, mutect2, varscan2
- APBB1IP | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1239954436, COSV66132958; called by muse, mutect2, varscan2
- APOB | c.11273T>C p.V3758A | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs998871696, COSV51950492; called by muse, mutect2, varscan2
- APOB | c.7591G>A p.E2531K | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs149358359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP21 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV57610649; called by muse, mutect2, varscan2
- ARMT1 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV66179041; called by muse, mutect2, varscan2
- ARNTL2 | c.1680G>C p.E560D | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV53828674; called by muse, mutect2
- ARPP21 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV51807300; called by muse, mutect2, varscan2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ATG16L2 | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.177); catalogued as COSV58362799; called by muse, mutect2, varscan2
- ATP2A1 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63922332; called by muse, mutect2, varscan2
- AVP | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1404819303, COSV66672170; called by muse, mutect2, varscan2
- BMT2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV51780592; called by muse, mutect2, varscan2
- C4A | c.3178C>T p.R1060W | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779962386, COSV71177977; called by muse, mutect2, varscan2
- C6orf226 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1375271495, COSV100491765; called by muse, mutect2, varscan2
- CACNG2 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV55639630; called by muse, mutect2, varscan2
- CCDC60 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV59549926; called by muse, mutect2, varscan2
- CCR8 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300357681, COSV58337917; called by muse, mutect2, varscan2
- CD3D | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT tolerated (0.5); PolyPhen benign (0.04); catalogued as COSV56141043; called by muse, mutect2, varscan2
- CDH9 | c.1390A>G p.N464D | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.02); catalogued as COSV50419758; called by muse, varscan2
- CDK12 | c.3937C>T p.P1313S (on ENST00000447079 / NM_016507.4; = p.P1304S on NM_015083.3) | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV71002735; called by muse, mutect2, varscan2
- CDSN | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 58/64 reads (91%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs565620030, COSV52539896; called by muse, mutect2, varscan2
- CENPI | c.530G>C p.R177P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as COSV54505958, COSV54506416, COSV54506899; called by muse, mutect2, varscan2
- CEP131 | c.1528A>T p.K510* (on ENST00000269392 / NM_001319228.2; = p.K507* on NM_014984.4) | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV53956082; called by muse, mutect2, varscan2
- CFAP47 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.964); catalogued as rs751194528, COSV52880976, COSV52894430; called by muse, mutect2, varscan2
- CFAP58 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV63833426, COSV63836136; called by muse, mutect2, varscan2
- CFAP92 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs373049779; called by muse, mutect2, varscan2
- CHCHD1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65708627; called by muse, mutect2, varscan2
- CHGB | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV66761628; called by muse, mutect2, varscan2
- CHST9 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52431118, COSV52448047; called by muse, mutect2, varscan2
- CLEC4M | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50223966; called by muse, mutect2, varscan2
- CLHC1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 68/114 reads (60%) | catalogued as COSV63427096, COSV63427177; called by muse, mutect2, varscan2
- CMTR2 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 14/20 reads (70%) | catalogued as COSV57604890; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, mutect2, varscan2
- COCH | c.911G>A p.G304E (on ENST00000216361 / NM_001347720.1; = p.G239E on NM_004086.3) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217792358, COSV53552876; called by muse, mutect2, varscan2
- COP1 | c.1125G>T p.R375S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV58175158; called by muse, mutect2, varscan2
- CORO7 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV52033649; called by muse, mutect2, varscan2
- CPAMD8 | c.2944G>A p.V982I (on ENST00000651564; = p.V935I on NM_015692.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.199); catalogued as COSV71596596; called by muse, mutect2, varscan2
- CPS1 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392559810, HM080066, COSV51802375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYGA | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV58018753; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2, varscan2
- CSMD2 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs749349455, COSV53914620; called by muse, mutect2, varscan2
- CTSZ | c.810_811del p.G271Lfs*10 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs773414005; called by pindel, varscan2
- CXorf66 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as rs200754289, COSV65169523, COSV65169966; called by muse, mutect2, varscan2
- CYP2C18 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53673934; called by muse, mutect2, varscan2
- CYP2C8 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV64878575; called by muse, mutect2, varscan2
- CYP4B1 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 19/25 reads (76%) | catalogued as rs1164911847, COSV54725950; called by muse, mutect2, varscan2
- CYP4F22 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs189645644, COSV54111496; called by muse, mutect2, varscan2
- DCC | c.4308G>A p.M1436I | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV71440013; called by muse, mutect2, varscan2
- DCDC1 | c.5270G>A p.R1757Q (on ENST00000597505 / NM_001367979.1; = p.R864Q on NM_020869.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs770366975, COSV100360872, COSV58003136; called by muse, mutect2, varscan2
- DCDC1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60855251; called by muse, mutect2, varscan2
- DHX8 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1436967115, COSV52256279; called by muse, mutect2, varscan2
- DMBT1 | c.3353C>T p.S1118F (on ENST00000338354 / NM_001377530.1; = p.S619F on NM_004406.3) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100352462; called by mutect2, varscan2
- DNAH5 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV54249122; called by muse, mutect2, varscan2
- DNAH7 | c.8371G>A p.E2791K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773317190, COSV56763066; called by muse, mutect2, varscan2
- DNAH8 | c.7001C>T p.S2334F | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT tolerated (0.27); PolyPhen benign (0.257); catalogued as COSV59477060; called by muse, mutect2, varscan2
- DNAH8 | c.9214G>A p.D3072N | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV59477089; called by muse, mutect2, varscan2
- DNAH9 | c.2587C>T p.L863F | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52374463; called by muse, mutect2, varscan2
- DROSHA | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs558382994, COSV60778079; called by muse, mutect2, varscan2
- DSC1 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as rs774520872, COSV57150928; called by muse, mutect2, varscan2
- DSG2 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192016851, COSV55202542; called by muse, mutect2, varscan2
- DSG4 | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV57388054, COSV57397108; called by muse, mutect2, varscan2
- DST | c.3278C>T p.P1093L (on ENST00000361203 / NM_001374722.1; = p.P767L on NM_001723.6) | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs778194334, COSV55037410; called by muse, mutect2, varscan2
- DUS2 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 32/44 reads (73%) | catalogued as rs367696455; called by muse, mutect2, varscan2
- EIF3L | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 52/70 reads (74%) | catalogued as rs11551380, COSV67740066; called by muse, mutect2, varscan2
- EPHB3 | c.2848G>A p.G950R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs766762619, COSV57808955; called by muse, mutect2
- ERBB4 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53582089, COSV99626446; called by muse, mutect2, varscan2
- ERCC6 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63393980; called by muse, mutect2, varscan2
- ERICH3 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 104/129 reads (81%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as COSV58602480; called by muse, mutect2, varscan2
- EZH2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV57461905; called by muse, mutect2, varscan2
- FABP9 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66911803; called by muse, mutect2, varscan2
- FAM135B | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52750908; called by muse, mutect2, varscan2
- FAM135B | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV52723060; called by muse, mutect2, varscan2
- FAT3 | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53167671; called by muse, mutect2, varscan2
- FAT3 | c.10471G>A p.E3491K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs540269604, COSV53136685; called by muse, mutect2, varscan2
- FBXO40 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV57527204; called by muse, mutect2, varscan2
- FBXW12 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 103/213 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV56484367, COSV56485370; called by muse, mutect2, varscan2
- FGGY | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100363932, COSV58044669; called by muse, mutect2, varscan2
- FLVCR2 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV53164317; called by muse, mutect2, varscan2
- FMN2 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 85/98 reads (87%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs867593720, COSV60425183; called by muse, mutect2, varscan2
- FRYL | c.3815C>T p.S1272F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51960797; called by muse, mutect2, varscan2
- FYB2 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 61/70 reads (87%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58588801; called by muse, mutect2, varscan2
- GABBR2 | c.1890G>A p.M630I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV52317798; called by muse, mutect2, varscan2
- GABRB2 | c.982T>G p.Y328D | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50940112; called by muse, mutect2, varscan2
- GABRB3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.23); catalogued as COSV54659351; called by muse, mutect2, varscan2
- GCNA | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 179/444 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.024); catalogued as rs140761910, COSV65468143, COSV65468172; called by muse, varscan2
- GP5 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461740256, COSV59879983; called by muse, mutect2, varscan2
- GPR139 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100429540, COSV58504859; called by muse, mutect2, varscan2
- GRID2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV56259488; called by muse, mutect2, varscan2
- GRIN3A | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.769); catalogued as COSV62457780; called by muse, mutect2, varscan2
- HAMP | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55886021; called by muse, mutect2, varscan2
- HAO2 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs587689040, COSV58039641; called by muse, mutect2, varscan2
- HYDIN | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100377378, COSV58570721; called by muse, mutect2, varscan2
- IGHG3 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT tolerated (0.29); catalogued as rs760455676; called by muse, mutect2, varscan2
- IGHMBP2 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 335/415 reads (81%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs147001168; called by muse, mutect2, varscan2
- INSRR | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 86/95 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747555254, COSV63876936; called by muse, mutect2, varscan2
- INTS3 | c.2696A>T p.N899I | Missense Mutation (SNP) | VAF 57/61 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV55165558; called by muse, mutect2, varscan2
- IQCH | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140529181; called by muse, mutect2, varscan2
- IQSEC3 | c.1015C>T p.R339C (on ENST00000538872 / NM_001170738.2; = p.R36C on NM_015232.1) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58280238; called by muse, mutect2, varscan2
- ITGB4 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV52332009; called by muse, mutect2, varscan2
- JAKMIP3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100059523; called by muse, mutect2, varscan2
- KIAA0513 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.34); PolyPhen benign (0.137); catalogued as rs1170338290, COSV50744145; called by muse, mutect2, varscan2
- KIAA0895 | c.1044G>A p.W348* (on ENST00000297063 / NM_001100425.2; = p.W297* on NM_015314.3) | Nonsense Mutation (SNP) | VAF 46/97 reads (47%) | catalogued as COSV51713732; called by muse, mutect2, varscan2
- KIAA1210 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as COSV68179854; called by muse, mutect2, varscan2
- KIAA1217 | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377180715; called by muse, mutect2, varscan2
- KIAA1549 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs768849251, COSV99651392; called by muse, varscan2
- KIF4A | c.1962G>A p.M654I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV65545572; called by muse, mutect2, varscan2
- KIFC1 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 93/110 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65737883; called by muse, mutect2, varscan2
- KIRREL2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV52879647; called by muse, mutect2, varscan2
- KLHL36 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1337327522, COSV99256950; called by muse, mutect2, varscan2
- KLHL40 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV55137137; called by muse, mutect2, varscan2
- KRT17 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV60861887; called by muse, mutect2, varscan2
- KRTAP13-4 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs764563782, COSV61880061; called by muse, mutect2, varscan2
- KSR2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs765242951, COSV56666019; called by muse, mutect2, varscan2
- L1CAM | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1267143652, COSV62829954; called by muse, mutect2, varscan2
- L3MBTL4 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53138723; called by muse, mutect2, varscan2
- LAMC3 | c.4609C>T p.Q1537* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV55989504; called by muse, mutect2
- LIN28B | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV61497436; called by muse, varscan2
- LIN28B | c.721G>C p.G241R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61497440; called by muse, mutect2, varscan2
- LIPI | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs868287819, COSV60709103; called by muse, mutect2, varscan2
- LPA | c.3878G>A p.R1293K | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.93); catalogued as rs778176623, COSV60310852; called by muse, mutect2, varscan2
- LRBA | c.6005C>T p.S2002L | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63963715; called by muse, mutect2, varscan2
- LRRC37A | c.4906G>A p.E1636K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100208222; called by mutect2, varscan2
- LRTM1 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as rs532949078, COSV55524497; called by muse, mutect2, varscan2
- MAP3K19 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.335); catalogued as rs866824136, COSV59636880, COSV59641925; called by muse, mutect2, varscan2
- MARS2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56572337; called by muse, mutect2, varscan2
- MATN4 | c.994G>A p.D332N (on ENST00000372754; = p.D291N on NM_003833.4) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | PolyPhen benign (0.2); catalogued as COSV61352838; called by muse, mutect2, varscan2
- MCF2L2 | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV61060577; called by muse, mutect2, varscan2
- MCHR1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs150937708, COSV99967864; called by mutect2, varscan2
- MED12L | c.5273G>A p.G1758E | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.235); catalogued as COSV56386003; called by muse, mutect2, varscan2
- METAP1D | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189556395, COSV59932078; called by muse, mutect2, varscan2
- MFSD6L | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs750408403, COSV61002664; called by muse, mutect2, varscan2
- MMP3 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV55407906; called by muse, mutect2, varscan2
- MRPL21 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV100751938; called by muse, mutect2, varscan2
- MRPS5 | c.672G>A p.E224= | Splice Region (SNP) | VAF 25/93 reads (27%) | catalogued as COSV55535277; called by muse, mutect2, varscan2
- MTM1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60337440; called by muse, mutect2, varscan2
- MTREX | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs766432922, COSV57925266; called by muse, mutect2, varscan2
- MUC16 | c.29186C>T p.S9729F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV67458275, COSV67488653, COSV67490325; called by muse, mutect2, varscan2
- MUC16 | c.19538C>T p.S6513F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs1217887114, COSV67454232; called by muse, mutect2, varscan2
- MUC16 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.197); catalogued as COSV67461597, COSV67490340; called by muse, mutect2, varscan2
- MYO3A | c.4001G>A p.R1334K | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56347105, COSV56348641; called by muse, mutect2, varscan2
- MYO3B | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV58694770; called by muse, mutect2, varscan2
- MYOCD | c.2246-1G>A p.X749_splice | Splice Site (SNP) | VAF 26/36 reads (72%) | catalogued as COSV58496593; called by muse, mutect2, varscan2
- NAALAD2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs139378419; called by muse, mutect2, varscan2
- NBEA | c.8423C>T p.T2808I | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59819307; called by muse, mutect2, varscan2
- NCKAP5 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs1019930330, COSV58450510, COSV58452261; called by muse, mutect2, varscan2
- NDUFAF6 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV54410563; called by muse, mutect2, varscan2
- NID2 | c.3166G>A p.G1056R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1318952059, COSV53500382; called by muse, mutect2, varscan2
- NLRC5 | c.5163C>T p.I1721= | Splice Region (SNP) | VAF 39/52 reads (75%) | catalogued as COSV52660551; called by muse, mutect2, varscan2
- NLRP11 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs141366900; called by muse, mutect2, varscan2
- NLRP7 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 169/444 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.243); catalogued as rs867213400, COSV60175213; called by muse, mutect2
- NMUR2 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs200730009, COSV54918681; called by muse, mutect2, varscan2
- NOX3 | c.387G>A p.W129* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV50162360; called by muse, mutect2, varscan2
- NPAP1 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV61510775; called by muse, mutect2, varscan2
- NRIP2 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV61702076; called by muse, mutect2
- NUP62CL | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV65236912; called by muse, mutect2, varscan2
- NYAP2 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.994); catalogued as COSV56015572; called by muse, mutect2, varscan2
- OR14K1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 72/79 reads (91%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV51720294, COSV99314976, COSV99315195; called by muse, mutect2, varscan2
- OR2A25 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV68717067; called by muse, mutect2, varscan2
- OR2C3 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 120/132 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV63576113; called by muse, mutect2, varscan2
- OR2M3 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 355/394 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs267598500, COSV71759081; called by muse, mutect2, varscan2
- OR2T27 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs749571834, COSV100788313; called by muse, mutect2, varscan2
- OR4A15 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as COSV59036335; called by muse, mutect2, varscan2
- OR51D1 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV62914796; called by muse, mutect2, varscan2
- OR51G1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs758959087, COSV58969086; called by muse, mutect2, varscan2
- OR52K1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV56903226; called by muse, mutect2, varscan2
- OR5I1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56886245; called by muse, mutect2, varscan2
- OR5W2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV60618188; called by muse, mutect2, varscan2
- OR8A1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as rs769868592, COSV52510235; called by muse, mutect2, varscan2
- OTOA | c.2097G>A p.M699I (on ENST00000286149; = p.M685I on NM_144672.4) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs763903896, COSV53763315; called by muse, mutect2, varscan2
- OVGP1 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as COSV63860011; called by muse, mutect2, varscan2
- P4HA1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as COSV54961447; called by muse, mutect2, varscan2
- PCARE | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 64/161 reads (40%) | catalogued as COSV59057750; called by muse, mutect2, varscan2
- PCDH11X | c.3877G>A p.D1293N | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV53500537; called by muse, mutect2, varscan2
- PCDH18 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61268111; called by muse, mutect2
- PCDHB2 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV52037338; called by muse, mutect2, varscan2
- PCDHGA9 | c.2180C>A p.A727D | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV54022010; called by muse, mutect2, varscan2
- PDIA5 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.866); catalogued as COSV100299596; called by muse, mutect2, varscan2
- PDILT | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 57/142 reads (40%) | catalogued as COSV56704908; called by muse, mutect2, varscan2
- PDZK1IP1 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV53744555; called by muse, mutect2, varscan2
- PIK3AP1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536725; called by muse, mutect2, varscan2
- PLEKHG4B | c.1453G>A p.E485K (on ENST00000283426; = p.E841K on NM_052909.5) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV52054310; called by muse, mutect2, varscan2
- PLG | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757693607, COSV57514182; called by muse, mutect2, varscan2
- POP1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs747730830, COSV62894046; called by muse, mutect2, varscan2
- PPFIA2 | c.3043G>A p.A1015T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61035590, COSV61052159; called by muse, mutect2, varscan2
- PPP1R9A | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs781010500, COSV56908874; called by muse, mutect2, varscan2
- PRKCQ | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV54118410; called by muse, mutect2, varscan2
- PRLH | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs144703716; called by muse, mutect2, varscan2
- PROKR2 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV54088820; called by muse, mutect2, varscan2
- PRSS37 | c.35-1G>A p.X12_splice | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as COSV63340075; called by muse, mutect2, varscan2
- PRTG | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV66840410; called by muse, mutect2, varscan2
- PSD3 | c.1930T>G p.S644A | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.68); PolyPhen benign (0.19); catalogued as COSV54079406; called by muse, varscan2
- PSG7 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 215/540 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs376395338; called by muse, mutect2, varscan2
- PSORS1C1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 82/100 reads (82%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); catalogued as COSV52536517; called by muse, mutect2, varscan2
- RASGRF1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV69182922; called by muse, mutect2, varscan2
- RASSF6 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780490961, COSV56720309; called by muse, varscan2
- RB1CC1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1357096073, COSV50272308; called by muse, mutect2, varscan2
- RIPOR3 | c.1771G>A p.G591S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.049); catalogued as rs1289903972, COSV50402574; called by muse, mutect2
- RNF111 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 66/140 reads (47%) | catalogued as COSV62088771; called by muse, mutect2, varscan2
- RNF128 | c.545C>T p.S182F (on ENST00000255499 / NM_194463.2; = p.S156F on NM_024539.3) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV55254217; called by muse, mutect2, varscan2
- SALL1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0.214); catalogued as COSV51764076, COSV51766047; called by muse, mutect2, varscan2
- SALL1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.824); catalogued as COSV51761770; called by muse, mutect2, varscan2
- SCN10A | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs760579685, COSV71862589; called by muse, mutect2, varscan2
- SCN1A | c.2752G>A p.D918N (on ENST00000303395 / NM_001202435.3; = p.D907N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as CD104857, COSV57668537, COSV57685331; called by muse, mutect2, varscan2
- SCN3A | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1304665415, COSV51821989, COSV51824418; called by muse, mutect2, varscan2
- SCRN1 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV54133655, COSV99622028; called by muse, mutect2, varscan2
- SH3TC1 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1309187912, COSV55283454; called by muse, mutect2, varscan2
- SIGLEC12 | c.1616C>T p.S539F (on ENST00000291707 / NM_053003.4; = p.S421F on NM_033329.2) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.619); catalogued as COSV52461696; called by muse, mutect2, varscan2
- SLC15A2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55200208; called by muse, mutect2, varscan2
- SLC15A3 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50021026; called by muse, mutect2, varscan2
- SLC36A2 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV58861993; called by muse, mutect2, varscan2
- SLC4A8 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV60654471; called by muse, mutect2, varscan2
- SLC6A14 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV64148599; called by muse, mutect2, varscan2
- SLC9A3 | c.1260T>A p.F420L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV53804959; called by muse, mutect2, varscan2
- SLITRK2 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59425634; called by muse, mutect2, varscan2
- SLITRK2 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV59428313; called by muse, mutect2, varscan2
- SLITRK4 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV62025907; called by muse, mutect2, varscan2
- SMC4 | c.1645C>G p.P549A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100644028, COSV100644088; called by muse, mutect2, varscan2
- SNCAIP | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV54420382; called by muse, mutect2, varscan2
- SORL1 | c.3551G>A p.R1184K | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV52761798; called by muse, mutect2, varscan2
- SPAG17 | c.5633C>T p.S1878F | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs769078202, COSV60467502; called by muse, mutect2, varscan2
- SPATA16 | c.589G>T p.G197* | Nonsense Mutation (SNP) | VAF 57/145 reads (39%) | catalogued as rs889856302, COSV63529618, COSV63532833; called by muse, mutect2, varscan2
- SPATA18 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs768840106, COSV54643648; called by muse, mutect2, varscan2
- SPATA31A3 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.65); PolyPhen benign (0.063); catalogued as rs565950783; called by muse, mutect2, varscan2
- SPRY3 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57142601, COSV57144254; called by muse, mutect2, varscan2
- STAMBP | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59898333; called by muse, mutect2, varscan2
- STPG2 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1315863946, COSV54816035; called by muse, varscan2
- STX1B | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV53062144, COSV53062428; called by muse, mutect2, varscan2
- SV2C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769027251, COSV59228129; called by muse, mutect2, varscan2
- SYP | c.164T>G p.V55G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54296889; called by muse, mutect2, varscan2
- SYT1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54071502; called by muse, mutect2, varscan2
- SYT10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767119363, COSV57338723; called by muse, mutect2, varscan2
- SYTL2 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs778208145, COSV60360942; called by muse, mutect2
- TAB2 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53855146; called by muse, mutect2, varscan2
- TACC1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV52528299; called by muse, mutect2, varscan2
- TACC2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV57771370; called by muse, mutect2, varscan2
- TACC2 | c.3624G>A p.M1208I | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57765120; called by muse, mutect2, varscan2
- TACR2 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV64822732; called by muse, mutect2, varscan2
- TAS2R4 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56094084; called by muse, mutect2, varscan2
- TBC1D1 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99791727; called by muse, mutect2, varscan2
- TEX13B | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | catalogued as COSV57203796; called by muse, mutect2, varscan2
- THSD7B | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs267598895, COSV55707231; called by muse, mutect2, varscan2
- THSD7B | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs1047471973, COSV55733035; called by muse, mutect2, varscan2
- TJP1 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV62046162; called by muse, mutect2, varscan2
- TLL1 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV50264867; called by muse, mutect2, varscan2
- TMEM207 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV61562248; called by muse, mutect2, varscan2
- TMPRSS3 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760379793, COSV52301281, COSV52307179; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4571C>T p.T1524I | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV100836153; called by muse, mutect2, varscan2
- TNXB | c.6155C>T p.S2052F (on ENST00000647633; = p.S1805F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64488096; called by muse, mutect2, varscan2
- TRANK1 | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1026042003, COSV57162833; called by muse, mutect2, varscan2
- TRHDE | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV53838762; called by muse, mutect2, varscan2
- TRIM46 | c.374T>G p.V125G | Missense Mutation (SNP) | VAF 287/314 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV55280185; called by muse, mutect2, varscan2
- TRIP4 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV56033228; called by muse, mutect2, varscan2
- TRPC7 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV61453665; called by muse, mutect2, varscan2
- TSC2 | c.2611A>C p.I871L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as COSV54778683; called by muse, mutect2, varscan2
- TSPOAP1 | c.5342C>T p.S1781F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52116785; called by muse, mutect2, varscan2
- TTN | c.74629G>A p.E24877K (on ENST00000591111; = p.E17453K on NM_003319.4) | Missense Mutation (SNP) | VAF 91/192 reads (47%) | PolyPhen benign (0.116); catalogued as COSV60312071; called by muse, mutect2, varscan2
- TTN | c.20821C>T p.P6941S (on ENST00000591111; = p.P6014S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | PolyPhen benign (0.194); catalogued as rs761911665, COSV100633463, COSV60312179; called by muse, mutect2, varscan2
- TTN | c.16993G>A p.E5665K (on ENST00000591111; = p.E4738K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/119 reads (44%) | PolyPhen possibly damaging (0.6); catalogued as COSV60312201; called by muse, mutect2, varscan2
- TUBB1 | c.461A>T p.K154M | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV53888241; called by muse, mutect2, varscan2
- UBQLN3 | c.1136G>A p.R379K | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV61165558; called by muse, mutect2, varscan2
- UBR2 | c.4217C>T p.P1406L | Missense Mutation (SNP) | VAF 126/141 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV65752363; called by muse, mutect2, varscan2
- ULK1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58859718; called by muse, mutect2, varscan2
- USH1G | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752343151, COSV58883368; called by muse, mutect2, varscan2
- VIM | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as COSV56407527; called by muse, mutect2, varscan2
- VWA8 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); catalogued as COSV55704635; called by muse, mutect2, varscan2
- WDHD1 | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs762999877, COSV62215493; called by muse, mutect2, varscan2
- WHRN | c.1849T>C p.S617P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV54334491; called by muse, mutect2, varscan2
- WIF1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54135425; called by muse, mutect2, varscan2
- WIZ | c.3997C>T p.R1333W (on ENST00000673675 / NM_001371589.1; = p.R238W on NM_021241.3) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751913380, COSV54612072; called by muse, mutect2, varscan2
- WNK1 | c.4490C>T p.S1497L (on ENST00000315939 / NM_018979.4; = p.S1250L on NM_014823.3) | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV60044141; called by muse, mutect2, varscan2
- YTHDC2 | c.2572C>T p.L858F | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99363630; called by muse, mutect2, varscan2
- ZAN | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV61815641; called by muse, mutect2, varscan2
- ZFP2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63726903; called by muse, mutect2, varscan2
- ZNF10 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs143738546; called by muse, varscan2
- ZNF384 | c.1447C>T p.Q483* (on ENST00000361959; = p.Q422* on NM_133476.5) | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV58556310; called by muse, mutect2, varscan2
- ZNF81 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV58578374; called by muse, mutect2, varscan2
- ZNF846 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67412583; called by muse, mutect2, varscan2
- ZXDB | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66493447; called by muse, mutect2, varscan2
- GSTO1 | c.357_359del p.L119del | In Frame Del (DEL) | VAF 24/89 reads (27%) | called by pindel, varscan2
- MLANA | c.155_174+30del p.X52_splice | Splice Site (DEL) | VAF 26/53 reads (49%) | called by mutect2, pindel
- PLG | c.883_884del p.T295Lfs*13 | Frame Shift Del (DEL) | VAF 33/112 reads (29%) | called by pindel, varscan2
- PTPN20 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 87/384 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- RBP3 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP1 | c.2005_2007del p.L669del | In Frame Del (DEL) | VAF 74/88 reads (84%) | called by pindel, varscan2
- ZNF572 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- ABCC6 | c.3531C>T p.L1177= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1358722561, COSV52747509, COSV52748663; called by muse, mutect2, varscan2
- ACKR4 | c.42G>A p.E14= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99392345; called by muse, mutect2, varscan2
- ACSL4 | c.1308C>T p.V436= (on ENST00000340800 / NM_022977.2; = p.V395= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV61615716; called by muse, mutect2, varscan2
- ACTL9 | c.1128G>A p.R376= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs1354488069, COSV61005593; called by muse, mutect2, varscan2
- ADAD1 | c.96G>A p.T32= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as rs755853675, COSV56641340; called by muse, mutect2, varscan2
- ADGRD1 | c.2004G>A p.E668= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV55456152; called by muse, mutect2, varscan2
- ADGRL2 | c.1452G>A p.R484= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs1048814222, COSV54674441; called by muse, mutect2, varscan2
- ADGRV1 | c.16455G>A p.Q5485= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV67984115, COSV67994367; called by muse, mutect2, varscan2
- ADRA2A | c.1251C>T p.S417= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs201804522, COSV54529847; called by muse, mutect2, varscan2
- AGR3 | c.207G>A p.E69= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV60037694; called by muse, mutect2, varscan2
- AK8 | c.969G>A p.K323= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV53760101; called by muse, mutect2, varscan2
- ALG12 | c.180C>T p.F60= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs202026974, COSV58208320; called by muse, mutect2, varscan2
- APLNR | c.375C>T p.F125= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs774293001, COSV57243922; called by muse, mutect2, varscan2
- APOB | c.9450C>T p.F3150= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as COSV51950504; called by muse, mutect2, varscan2
- ASB10 | c.1344C>T p.L448= (on ENST00000420175 / NM_001142459.2; = p.L433= on NM_080871.4) | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV51994434; called by muse, mutect2, varscan2
- ATCAY | c.159C>T p.F53= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV56657436; called by muse, mutect2, varscan2
- ATR | c.2820C>T p.S940= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV63391727; called by muse, mutect2, varscan2
- BTBD11 | c.2616C>T p.I872= (on ENST00000280758 / NM_001018072.2; = p.I409= on NM_001017523.2) | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV55036083; called by muse, mutect2, varscan2
- C6orf226 | c.180C>T p.P60= | Silent (SNP) | VAF 51/65 reads (78%) | catalogued as COSV100491763; called by muse, mutect2, varscan2
- CACNA1C | c.4179C>T p.I1393= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV59730320, COSV59765008; called by muse, mutect2, varscan2
- CACNA1C | c.4911G>A p.Q1637= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV59765056; called by muse, mutect2, varscan2
- CACNA2D3 | c.429G>A p.G143= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs267599904, COSV55518510; called by muse, mutect2, varscan2
- CACNA2D3 | c.2682C>T p.S894= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV55577560, COSV55578584; called by muse, mutect2, varscan2
- CACNA2D3 | c.3009C>T p.I1003= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1400092460, COSV55577574; called by muse, mutect2, varscan2
- CADM3 | c.1011G>A p.V337= (on ENST00000368125 / NM_001127173.3; = p.V371= on NM_021189.5) | Silent (SNP) | VAF 78/87 reads (90%) | catalogued as COSV63676212, COSV63677240; called by muse, mutect2, varscan2
- CAMSAP3 | c.1020C>T p.A340= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV50358640; called by muse, mutect2, varscan2
- CC2D1A | c.1653C>T p.A551= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as rs370966628; called by muse, mutect2, varscan2
- CCDC59 | c.135C>T p.F45= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1047041123, COSV50261708; called by muse, mutect2, varscan2
- CCNB3 | c.1077G>A p.E359= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV52079178; called by muse, mutect2, varscan2
- CDH12 | c.483G>A p.L161= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as COSV66443965; called by muse, mutect2, varscan2
- CDH9 | c.1323C>T p.F441= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV50419931; called by muse, varscan2
- CDH9 | c.429G>A p.S143= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as rs748753503, COSV50274627, COSV99142992; called by muse, mutect2, varscan2
- CELSR3 | c.858C>T p.F286= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1249399135, COSV51144240; called by muse, mutect2, varscan2
- CHL1 | c.945C>T p.F315= (on ENST00000397491 / NM_001253387.1; = p.F331= on NM_006614.4) | Silent (SNP) | VAF 68/163 reads (42%) | catalogued as COSV56604976; called by muse, mutect2, varscan2
- CLEC4D | c.615G>A p.R205= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV55228216; called by muse, mutect2, varscan2
- CLSTN2 | c.1770C>T p.S590= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV71724581; called by muse, mutect2, varscan2
- CNTF | c.132G>A p.L44= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as COSV60161667; called by muse, mutect2, varscan2
- COL6A3 | c.1614G>A p.T538= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as rs535142787, COSV55107209; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL9A1 | c.1458G>A p.R486= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV57892322; called by muse, mutect2, varscan2
- CRTAC1 | c.438C>T p.T146= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as rs768709165, COSV100085868, COSV54009009; called by muse, mutect2, varscan2
- CSMD3 | c.3700C>T p.L1234= (on ENST00000297405 / NM_001363185.1; = p.L1130= on NM_052900.3) | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs528521971, COSV52303989; called by muse, mutect2, varscan2
- CYLC2 | c.285G>A p.R95= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs761134343, COSV66339291; called by muse, mutect2, varscan2
- CYP2C18 | c.411G>A p.G137= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as rs1046402688, COSV53669874; called by muse, mutect2, varscan2
- CYSLTR1 | c.705C>T p.I235= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV64821190; called by muse, mutect2, varscan2
- DLG2 | c.1617C>T p.L539= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV54634367, COSV54681363; called by muse, mutect2, varscan2
- DMRT3 | c.1053C>T p.P351= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV51908447; called by muse, mutect2, varscan2
- DNMT3L | c.240C>T p.F80= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV54265880; called by muse, mutect2, varscan2
- DRAM2 | c.255G>A p.E85= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs779227254, COSV54416390; called by muse, mutect2, varscan2
- DSCAM | c.4215G>A p.G1405= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1363985269, COSV68035151; called by muse, mutect2, varscan2
- DSG2 | c.582G>A p.S194= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs748768578, COSV55198230; called by muse, mutect2, varscan2
- DUS2 | c.726C>T p.A242= | Silent (SNP) | VAF 33/45 reads (73%) | catalogued as COSV100732589; called by muse, mutect2, varscan2
- DVL1 | c.978C>T p.S326= | Silent (SNP) | VAF 38/40 reads (95%) | catalogued as COSV59565442; called by muse, mutect2, varscan2
- ERICH3 | c.4218G>A p.E1406= | Silent (SNP) | VAF 102/120 reads (85%) | catalogued as COSV58616967; called by muse, mutect2, varscan2
- ETV3L | c.435G>A p.G145= | Silent (SNP) | VAF 104/112 reads (93%) | catalogued as rs940499961, COSV71901199; called by muse, mutect2, varscan2
- FBXL18 | c.1464C>T p.L488= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs374566223, COSV66107859; called by muse, mutect2, varscan2
- FPGT | c.1182A>G p.L394= | Silent (SNP) | VAF 64/70 reads (91%) | catalogued as COSV100907384; called by muse, mutect2, varscan2
- GAPDH | c.342G>A p.G114= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs763523311, COSV57521997; called by muse, mutect2, varscan2
- GHR | c.1908C>T p.I636= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs866781710, COSV50112895; called by muse, mutect2, varscan2
- GPR158 | c.2907G>A p.K969= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV66272210; called by muse, mutect2, varscan2
- GPR65 | c.633G>A p.R211= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as COSV50863985; called by muse, mutect2, varscan2
- GRID2 | c.2217C>T p.F739= | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as rs780649095, COSV56171939; called by muse, mutect2, varscan2
- GRIN2A | c.1923C>T p.F641= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV58055199; called by muse, mutect2, varscan2
- GUCA1C | c.426C>T p.I142= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as rs746820657, COSV53752106; called by muse, mutect2, varscan2
- H3C3 | c.225C>T p.I75= | Silent (SNP) | VAF 58/74 reads (78%) | catalogued as rs983273765, COSV63551139, COSV63551526; called by muse, mutect2, varscan2
- HABP2 | c.552G>A p.G184= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV63637871; called by muse, mutect2, varscan2
- HHLA2 | c.306G>A p.G102= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV63317001; called by muse, mutect2, varscan2
- IGKV2-28 | c.294G>A p.L98= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1558733267; called by mutect2, varscan2
- IL20RA | c.675C>T p.P225= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV57360319; called by muse, mutect2, varscan2
- INPP5D | c.2730C>T p.I910= (on ENST00000445964 / NM_001017915.3; = p.I909= on NM_005541.5) | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV64038512; called by muse, mutect2, varscan2
- IQSEC2 | c.2520C>T p.F840= (on ENST00000642864 / NM_001111125.3; = p.F635= on NM_015075.2) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV64727724; called by muse, mutect2, varscan2
- IRAK3 | c.1038C>T p.I346= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV54163245; called by muse, mutect2, varscan2
- ITGA8 | c.900C>T p.I300= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV65235153; called by muse, mutect2, varscan2
- ITPRID1 | c.2925C>T p.I975= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV60081911; called by muse, mutect2, varscan2
- JAKMIP2 | c.999C>T p.L333= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as rs1468580713, COSV54614561; called by muse, mutect2, varscan2
- KCNC1 | c.1146G>A p.T382= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs760069085, COSV56393109; called by muse, mutect2
- KCNC2 | c.951C>T p.I317= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV54378663; called by muse, mutect2, varscan2
- KCTD14 | c.54C>T p.T18= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs928955596, COSV62001960; called by muse, mutect2, varscan2
- KIAA1549 | c.1578C>T p.G526= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs1252628193, COSV99651393; called by mutect2, varscan2
- KIF2B | c.594G>A p.L198= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV52134884; called by muse, mutect2, varscan2
- KMT2C | c.8838C>T p.S2946= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV51497029; called by muse, mutect2, varscan2
- LHFPL1 | c.168A>T p.G56= | Silent (SNP) | VAF 85/203 reads (42%) | catalogued as COSV64333663; called by muse, mutect2, varscan2
- LILRB3 | c.414G>A p.G138= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs1458918866; called by muse, varscan2
- LIN28B | c.465G>A p.Q155= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV61497429; called by muse, varscan2
- LRP1B | c.6126G>A p.P2042= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as rs751396734, COSV67269721; called by muse, mutect2, varscan2
- MAP3K21 | c.2373C>T p.P791= | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as COSV64042490; called by muse, mutect2, varscan2
- MB21D2 | c.387C>T p.D129= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV66665779; called by muse, mutect2, varscan2
- MCHR1 | c.87C>T p.P29= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1569373320, COSV99967865; called by muse, mutect2, varscan2
- MCOLN2 | c.597C>T p.S199= | Silent (SNP) | VAF 52/55 reads (95%) | catalogued as COSV52299336; called by muse, mutect2, varscan2
- MECOM | c.294G>A p.R98= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV72111206; called by muse, mutect2, varscan2
- MGAT4C | c.1371G>A p.R457= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs923771485, COSV59832801, COSV59834439; called by muse, mutect2, varscan2
- MKI67 | c.9384C>T p.S3128= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV64076597; called by muse, mutect2, varscan2
- MMP9 | c.1209C>T p.F403= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs1364279397, COSV63433765; called by muse, mutect2, varscan2
- MRPL21 | c.363C>T p.D121= | Silent (SNP) | VAF 53/461 reads (11%) | catalogued as COSV100751940; called by muse, mutect2, varscan2
- MSI2 | c.330G>A p.K110= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV52363421, COSV99401460; called by muse, mutect2
- MTUS2 | c.2193G>A p.K731= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV70921980; called by muse, mutect2, varscan2
- MUSK | c.1716G>A p.R572= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs747237685, COSV51895285, COSV99505262; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH8 | c.2631G>A p.E877= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as COSV67971618; called by muse, mutect2, varscan2
- MYO15A | c.5376C>T p.F1792= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV52765036; called by muse, mutect2, varscan2
- NEXMIF | c.3591G>A p.R1197= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs770401349, COSV50093978; called by muse, mutect2, varscan2
- NINL | c.2970C>T p.T990= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV54008134; called by muse, mutect2, varscan2
- NLRP10 | c.987G>A p.T329= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV60780787; called by muse, mutect2, varscan2
- NLRP4 | c.180C>T p.I60= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV56722291; called by muse, mutect2, varscan2
- NOTCH1 | c.6501C>T p.A2167= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV53090036; called by muse, mutect2, varscan2
- NPSR1 | c.873C>T p.F291= | Silent (SNP) | VAF 109/280 reads (39%) | catalogued as COSV62195883, COSV62200739; called by muse, mutect2, varscan2
- NPTX2 | c.1173C>T p.I391= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs750620530, COSV55717866; called by muse, mutect2, varscan2
- NUTM1 | c.3375G>A p.R1125= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as COSV59218781; called by muse, mutect2, varscan2
- OR13C4 | c.51C>T p.L17= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV52928343; called by muse, mutect2, varscan2
- OR52N2 | c.129G>A p.G43= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs1357159826, COSV57676521; called by muse, mutect2, varscan2
- OR5AR1 | c.624C>T p.F208= | Silent (SNP) | VAF 58/131 reads (44%) | catalogued as COSV57255179; called by muse, mutect2, varscan2
- OR5K1 | c.513G>A p.S171= | Silent (SNP) | VAF 108/262 reads (41%) | catalogued as rs367830052; called by muse, mutect2, varscan2
- OR8K1 | c.273C>T p.F91= | Silent (SNP) | VAF 67/173 reads (39%) | catalogued as COSV54404373; called by muse, mutect2, varscan2
- OR9G1 | c.492C>T p.S164= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV56453910; called by muse, mutect2
- OTOF | c.4194C>T p.P1398= (on ENST00000272371 / NM_194248.3; = p.P631= on NM_004802.4) | Silent (SNP) | VAF 52/79 reads (66%) | catalogued as rs749026372, COSV55505690; called by muse, mutect2, varscan2
- P2RX5 | c.264C>T p.V88= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as rs145941131; called by muse, mutect2, varscan2
- PANX2 | c.588C>T p.I196= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV50312160; called by muse, mutect2, varscan2
- PAPPA2 | c.1182C>T p.P394= | Silent (SNP) | VAF 47/55 reads (85%) | catalogued as COSV62785697; called by muse, mutect2, varscan2
- PCCB | c.408A>T p.A136= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99291517; called by muse, mutect2, varscan2
- PCDHA11 | c.1698G>A p.A566= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as COSV56541507; called by muse, mutect2, varscan2
- PCDHB11 | c.2313C>T p.I771= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs368891553; called by muse, mutect2, varscan2
- PCK1 | c.513G>A p.R171= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV60130837; called by muse, mutect2, varscan2
- PDIA5 | c.162C>T p.S54= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV100299597; called by muse, mutect2, varscan2
- PFKFB2 | c.252C>T p.S84= | Silent (SNP) | VAF 304/353 reads (86%) | catalogued as COSV65549706; called by muse, mutect2, varscan2
- PIGA | c.369G>A p.T123= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs766304305, COSV61238373; called by muse, mutect2, varscan2
- POU6F2 | c.1176C>T p.I392= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV68876019; called by muse, mutect2, varscan2
- PPARG | c.672G>A p.E224= (on ENST00000287820 / NM_015869.5; = p.E194= on NM_005037.7) | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV55145227; called by muse, mutect2, varscan2
- PRDM2 | c.2865C>T p.S955= | Silent (SNP) | VAF 109/144 reads (76%) | catalogued as COSV52454883; called by muse, mutect2, varscan2
- PRKAR2B | c.942C>T p.F314= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV55925806; called by muse, mutect2, varscan2
- PROM2 | c.1173C>T p.F391= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs753670733, COSV58300576; called by muse, mutect2, varscan2
- RBM12 | c.2406C>T p.P802= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs747155371, COSV58294674; called by muse, mutect2, varscan2
- RP1 | c.3894C>T p.F1298= | Silent (SNP) | VAF 96/153 reads (63%) | catalogued as COSV55115168; called by muse, mutect2, varscan2
- RP1L1 | c.3504G>A p.L1168= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV66759720; called by muse, mutect2, varscan2
- RTF1 | c.1809C>T p.I603= | Silent (SNP) | VAF 56/150 reads (37%) | catalogued as rs767608379, COSV67478166, COSV67478871; called by muse, mutect2, varscan2
- SCN4A | c.1947C>T p.I649= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs564134251, COSV71128888; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SH2D3C | c.969C>T p.F323= (on ENST00000314830 / NM_170600.3; = p.F166= on NM_005489.4) | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV59129088; called by muse, mutect2, varscan2
- SHOC1 | c.1728G>A p.R576= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV59506735; called by muse, mutect2, varscan2
- SIGLEC1 | c.1353C>T p.I451= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52458563; called by muse, mutect2, varscan2
- SLC13A3 | c.1413C>T p.I471= | Silent (SNP) | VAF 74/168 reads (44%) | catalogued as COSV51713040, COSV51721835; called by muse, varscan2
- SLC25A5 | c.636C>T p.I212= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as COSV100510502, COSV58629753; called by muse, mutect2, varscan2
- SLC4A8 | c.1716C>T p.F572= | Silent (SNP) | VAF 64/146 reads (44%) | catalogued as COSV60657772; called by muse, mutect2, varscan2
- SLC4A9 | c.1743A>T p.I581= (on ENST00000507527 / NM_001258428.2; = p.I557= on NM_031467.3) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV50208805; called by muse, mutect2
- SLC8A1 | c.2637C>T p.F879= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV60470955; called by muse, mutect2, varscan2
- SMC4 | c.1644C>T p.L548= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100644026; called by muse, mutect2, varscan2
- SORL1 | c.1161G>A p.E387= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV52761789; called by muse, mutect2, varscan2
- SPINK5 | c.1785C>T p.I595= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV56252186; called by muse, mutect2, varscan2
- SPTB | c.4449C>T p.I1483= | Silent (SNP) | VAF 58/74 reads (78%) | catalogued as rs199822834; called by muse, mutect2, varscan2
- SYNDIG1 | c.393G>A p.G131= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as COSV65231825; called by muse, mutect2, varscan2
- TELO2 | c.582G>A p.R194= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs1405731378, COSV51980944; called by muse, mutect2, varscan2
- TENT5D | c.141G>A p.V47= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs1185851062, COSV57638824; called by muse, mutect2, varscan2
- TEX11 | c.1845G>A p.V615= (on ENST00000344304; = p.V600= on NM_031276.3) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV60238163; called by muse, mutect2, varscan2
- TLR5 | c.2262C>T p.I754= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs780943112, COSV60557822, COSV60559477; called by muse, mutect2, varscan2
- TMPRSS7 | c.915C>T p.T305= (on ENST00000452346; = p.T179= on NM_001042575.2) | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV69982446; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4572C>T p.T1524= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs1266780167, COSV100836152; called by muse, mutect2, varscan2
- TPSG1 | c.786G>A p.V262= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV52357742; called by muse, mutect2, varscan2
- TTN | c.65232G>A p.L21744= (on ENST00000591111; = p.L14320= on NM_003319.4) | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as COSV60034201; called by muse, mutect2, varscan2
- UNC5D | c.708C>T p.I236= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as rs764908615, COSV54767563, COSV54777646; called by muse, mutect2, varscan2
- WWC3 | c.2709G>A p.T903= | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as rs772197155, COSV66506965; called by muse, mutect2, varscan2
- XIAP | c.1240C>T p.L414= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV63021505, COSV63023764; called by muse, mutect2, varscan2
- YTHDC2 | c.2571C>T p.I857= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as COSV99363628; called by muse, mutect2, varscan2
- ZBED1 | c.57C>T p.P19= | Silent (SNP) | VAF 73/193 reads (38%) | catalogued as COSV58138429; called by muse, mutect2, varscan2
- ZNF556 | c.304A>C p.R102= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as COSV56914058; called by muse, mutect2, varscan2
- ZNF71 | c.1206C>T p.I402= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs145594416; called by muse, mutect2, varscan2
- ZPLD1 | c.837C>T p.F279= (on ENST00000466937 / NM_001329788.1; = p.F295= on NM_175056.2) | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs746914724, COSV60352581; called by muse, mutect2, varscan2
- ATP2B2 | c.908-1165C>T | Intron (SNP) | VAF 31/64 reads (48%) | catalogued as COSV59506545; called by muse, mutect2, varscan2
- CCDC33 | c.1291-11576C>T | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99173396; called by muse, mutect2, varscan2
- HERC2P3 | n.2309G>A | RNA (SNP) | VAF 16/129 reads (12%) | catalogued as rs762458368; called by muse, mutect2, varscan2
- IL18 | c.92-41G>A | Intron (SNP) | VAF 13/17 reads (76%) | catalogued as rs755487986; called by muse, mutect2, varscan2
- IL36B | c.261+853G>A | Intron (SNP) | VAF 39/83 reads (47%) | catalogued as rs748873308, COSV52089464, COSV99382955; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640669 G>A | 3'Flank (SNP) | VAF 20/27 reads (74%) | catalogued as rs199684141, COSV51704027; called by muse, mutect2, varscan2
- MIR516A2 | n.24G>A | RNA (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- MIR526A1 | n.7C>T | RNA (SNP) | VAF 44/130 reads (34%) | catalogued as rs1568611701; called by muse, mutect2, varscan2
- PRKCB | c.1864-5198G>A | Intron (SNP) | VAF 36/107 reads (34%) | catalogued as rs745816864, COSV57799242; called by muse, mutect2, varscan2
- SND1 | c.2110+457C>T | Intron (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100690801; called by muse, mutect2, varscan2
- TBC1D29P | n.2918C>T | RNA (SNP) | VAF 15/38 reads (39%) | catalogued as rs763764141, COSV70434297; called by muse, mutect2, varscan2
- TRO | c.*19C>T | 3'UTR (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99436016, COSV99436927; called by muse, mutect2, varscan2
